MMRF case MMRF_2456 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3ac7e06e-f847-4f1d-a858-3b2108a6173a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.6 years (25,793 days); ISS stage: I; Days to last known disease status: 488 days (1.3 years); Days to last follow up: 488 days (1.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 5 days; Days to treatment end: 124 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 5 days; Days to treatment end: 89 days.
   Treatment given: Therapeutic agents: Carfilzomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 153 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 0): M Protein 3.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 267 mg/dL; Immunoglobulin G 50 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.17 µg/mL; Hemoglobin 7.81 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3.04 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 9.3 g/dL; Glucose 6 mmol/L.
- Day 96 (ECOG 0): M Protein 2.5 g/dL; Immunoglobulin G 27.2 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.16 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Total Protein 7.9 g/dL; Glucose 7.21 mmol/L.
- Day 177 (ECOG 0): M Protein 1.7 g/dL; Immunoglobulin G 19.4 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.19 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 7.2 g/dL; Glucose 6 mmol/L.
- Day 264 (ECOG 0): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.37 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.27 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 5.72 mmol/L.
- Day 356 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 6.23 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.27 µg/mL; Hemoglobin 7.44 mmol/L; Leukocytes 5.18 ×10⁹/L; Absolute Neutrophil 4.16 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 6.49 mmol/L.
- Day 454 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 5.51 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.2 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 4.61 ×10⁹/L; Absolute Neutrophil 3.28 ×10⁹/L; Platelets 93 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 6.49 mmol/L.
- Day 488: M Protein 3.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Hemoglobin 6.63 mmol/L; Leukocytes 4.13 ×10⁹/L; Absolute Neutrophil 1.62 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 6 mmol/L.

Other clinical attributes
- Day -8: Weight: 85 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Melanoma; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2456_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_2456_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
